Somatic mutation profile of tumor specimen MMRF_2016_1_BM_CD138pos (aliquot MMRF_2016_1_BM_CD138pos_T1_KHS5U_L11065) from MMRF case MMRF_2016, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.4 years (27,888 days).
Specimen MMRF_2016_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32474446-66b4-4c24-82f7-29125f5c3893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2016_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2016_1_PB_WBC_C3_KHS5U_L08806; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bfa2920-f3eb-4607-ab15-cbbc9872dbc8

The open-access MAF lists 118 somatic variants for this specimen: 48 protein-altering or splice-affecting, 18 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 28, Silent 18, 5'UTR 10, Intron 7, RNA 3, 3'Flank 3, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC011005.1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761842703; called by muse, mutect2
- ADAMTS5 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs775648082, COSV53175705; called by muse, mutect2, varscan2
- APOBEC4 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs576075334, COSV58018105; called by muse, mutect2, varscan2
- C1orf131 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs757563319, COSV59643058; called by muse, mutect2, varscan2
- CCDC9 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs774173764, COSV55719599; called by muse, mutect2, varscan2
- CCDC9B | c.1508C>G p.P503R | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV66875654; called by muse, mutect2, varscan2
- CLCA4 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749833337; called by muse, mutect2, varscan2
- CLIP2 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | catalogued as rs1554312238, COSV56285920; called by muse, mutect2
- FEZF1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 149/183 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1222758396; called by muse, mutect2, varscan2
- GAS6 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as rs368447635; called by muse, mutect2, varscan2
- GPRC5A | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763496049; called by muse, mutect2, varscan2
- HTR6 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197300204, COSV99230181; called by muse, mutect2
- JAK3 | c.3096C>T p.A1032= | Splice Region (SNP) | VAF 8/110 reads (7%) | catalogued as COSV71686059; called by muse, mutect2
- LIPE | c.2344A>G p.K782E | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs755286945; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 49/308 reads (16%) | catalogued as rs760302326; called by mutect2, varscan2
- MYT1L | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746083137, COSV67714781; called by muse, mutect2, varscan2
- NALCN | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51933403; called by muse, mutect2
- OR1K1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 79/482 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs775486882, COSV104373757; called by muse, mutect2, varscan2
- PAX9 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 227/570 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs1215426320; called by muse, mutect2, varscan2
- PLEKHM1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs752002952; called by muse, mutect2, varscan2
- TAS1R2 | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs370068569, COSV100946288; called by muse, mutect2, varscan2
- TLR10 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1356608599; called by muse, mutect2, varscan2
- TNS1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs377270295; called by muse, mutect2, varscan2
- WDR11 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as rs777677898; called by muse, mutect2, varscan2
- ARHGEF17 | c.2510T>A p.L837Q | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.184); called by muse, mutect2
- BAG6 | c.2950G>A p.V984I (on ENST00000676571; = p.V937I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARD10 | c.719A>T p.K240I | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- CCDC168 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- CFAP46 | c.6748C>A p.P2250T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DAB2IP | c.3451G>T p.A1151S (on ENST00000408936; = p.A1123S on NM_032552.3) | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- EDIL3 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- EHBP1L1 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPB41L2 | c.2840del p.G947Vfs*13 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GADD45GIP1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- HECTD4 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV3-7 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); called by muse, mutect2
- IL16 | c.1148T>C p.F383S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- KLHL6 | c.214A>C p.T72P | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMS19 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NR4A2 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PAGE2 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB8 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- SHKBP1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2
- STIM2 | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR1 | c.1544T>C p.V515A (on ENST00000382452; = p.V375A on NM_005112.5) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF324B | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGPAT4 | c.573G>A p.V191= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs1234119803; called by muse, mutect2, varscan2
- ASNS | c.300A>T p.I100= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- BMP2 | c.480T>G p.A160= | Silent (SNP) | VAF 87/299 reads (29%) | called by muse, mutect2, varscan2
- CPT2 | c.817C>T p.L273= | Silent (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- CREB5 | c.729C>T p.H243= (on ENST00000357727 / NM_182898.4; = p.H236= on NM_004904.3) | Silent (SNP) | VAF 44/358 reads (12%) | called by muse, mutect2, varscan2
- DNAH3 | c.36C>G p.A12= | Silent (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.252G>A p.R84= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV68106471; called by muse, mutect2, varscan2
- HSD17B2 | c.261G>T p.V87= | Silent (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- HSPB2 | c.528G>A p.E176= | Silent (SNP) | VAF 207/400 reads (52%) | called by muse, mutect2, varscan2
- ITSN1 | c.5049G>A p.A1683= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs190494297, COSV67157661; called by muse, mutect2, varscan2
- IVNS1ABP | c.849A>G p.Q283= | Silent (SNP) | VAF 93/214 reads (43%) | called by muse, mutect2, varscan2
- NECTIN1 | c.315C>T p.T105= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as rs777561931; called by muse, mutect2, varscan2
- OCA2 | c.351T>C p.H117= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.639G>A p.P213= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs543769912; called by muse, mutect2, varscan2
- RSPH3 | c.381C>T p.C127= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- STARD9 | c.12021A>G p.T4007= | Silent (SNP) | VAF 39/254 reads (15%) | called by muse, mutect2, varscan2
- TSPAN9 | c.249C>A p.L83= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as COSV99170865; called by muse, mutect2
- ZNF850 | c.792G>A p.P264= | Silent (SNP) | VAF 54/404 reads (13%) | catalogued as rs568650132; called by muse, mutect2
- AC015911.9 | n.512G>T | RNA (SNP) | VAF 70/362 reads (19%) | catalogued as rs769235088; called by muse, mutect2, varscan2
- ADGRG6 | c.*1987A>G | 3'UTR (SNP) | VAF 70/128 reads (55%) | catalogued as rs373223780; called by muse, mutect2, varscan2
- ANKK1 | c.-78G>T | 5'UTR (SNP) | VAF 56/187 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.4012-175A>G | Intron (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- C7orf66 | n.306A>G | RNA (SNP) | VAF 61/379 reads (16%) | called by muse, mutect2, varscan2
- CACNA1H | c.4351-50G>A | Intron (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- CCNB1 | c.*87A>T | 3'UTR (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- CDIP1 | c.*17G>A | 3'UTR (SNP) | VAF 27/162 reads (17%) | catalogued as rs760413820; called by muse, mutect2, varscan2
- CELF2 | c.*3254C>A | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- COL5A3 | c.*256A>C | 3'UTR (SNP) | VAF 22/132 reads (17%) | catalogued as rs965843247; called by muse, mutect2
- COPS2 | c.*1213A>G | 3'UTR (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- DCTN4 | c.*188C>G | 3'UTR (SNP) | VAF 13/158 reads (8%) | catalogued as rs1451145689; called by muse, mutect2
- DDX60 | c.*161A>G | 3'UTR (SNP) | VAF 43/203 reads (21%) | catalogued as rs1040375156; called by muse, mutect2, varscan2
- DEPTOR | c.-22G>A | 5'UTR (SNP) | VAF 51/234 reads (22%) | called by muse, mutect2, varscan2
- DUSP6 | c.-433G>A | 5'UTR (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- ECHDC1 | c.-168G>A | 5'UTR (SNP) | VAF 110/222 reads (50%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.*2006A>C | 3'UTR (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- EPHA7 | c.*2565A>C | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- FOXP1 | c.180+305T>G | Intron (SNP) | VAF 113/211 reads (54%) | called by muse, mutect2, varscan2
- GABRA2 | c.*614G>A | 3'UTR (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- GALNT13 | c.*360A>G | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- GCSAML | c.*1112C>T | 3'UTR (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- GPATCH2 | c.*1088G>T | 3'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- HDAC10 | c.-225G>A | 5'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- HLA-DMA | c.373+154T>A | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- IYD | c.*5038C>T | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- KCNV1 | c.-79C>T | 5'UTR (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- KRTAP6-1 | c.-1C>T | 5'UTR (SNP) | VAF 87/226 reads (38%) | catalogued as COSV100228844; called by muse, mutect2, varscan2
- MGAT1 | c.-59_-44del | 5'UTR (DEL) | VAF 41/186 reads (22%) | called by mutect2, pindel, varscan2
- NDUFV3 | c.170-5639G>T | Intron (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- NFASC | c.-26G>A | 5'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- NOX4 | chr11:89491460 C>T | 5'Flank (SNP) | VAF 25/153 reads (16%) | catalogued as rs1316189006; called by muse, mutect2, varscan2
- NSD1 | c.*1082T>C | 3'UTR (SNP) | VAF 85/158 reads (54%) | called by muse, mutect2, varscan2
- OCIAD1 | c.*286C>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- PBX2 | c.-2C>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- PCLO | c.14791+38A>G | Intron (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*2857C>A | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- RAVER2 | c.1929+13C>G | Intron (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2
- RN7SL860P | chr19:22602378 C>T | 3'Flank (SNP) | VAF 7/119 reads (6%) | catalogued as rs1021487671; called by muse, mutect2
- SAMD9 | c.*1113A>C | 3'UTR (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- SIGLEC17P | n.586C>T | RNA (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- SNORD114-7 | chr14:100967257 A>G | 3'Flank (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- SNPH | c.*2680C>A | 3'UTR (SNP) | VAF 30/301 reads (10%) | called by muse, mutect2
- SS18L2 | c.*551_*552del | 3'UTR (DEL) | VAF 76/187 reads (41%) | called by pindel, varscan2
- TMPRSS11A | c.*744T>G | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TPSD1 | chr16:1262841 G>A | 3'Flank (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- TULP1 | c.*277T>G | 3'UTR (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- UBE2K | c.*3725T>G | 3'UTR (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- UBN2 | c.*1196A>G | 3'UTR (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- UNC80 | c.*797G>C | 3'UTR (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- ZBTB46 | c.*2690_*2691insTT | 3'UTR (INS) | VAF 32/88 reads (36%) | called by mutect2, pindel*, varscan2
- ZCCHC7 | c.*348_*352del | 3'UTR (DEL) | VAF 15/60 reads (25%) | catalogued as rs1022232564; called by mutect2, pindel, varscan2
